Somatic mutation profile of tumor specimen d1034660-11ce-4e38-9ad0-8b9b72 (aliquot d1034660-11ce-4e38-9ad0-8b9b72_D6) from CPTAC case 14BR014, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,565 days).
Specimen d1034660-11ce-4e38-9ad0-8b9b72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b89474-f316-407b-81e3-968fb926cfe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 15f928a5-e824-477a-9882-0f1029 (Blood Derived Normal), aliquot 15f928a5-e824-477a-9882-0f1029_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6ec241c-8d73-4011-8e54-d55fd551eeae

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, 5'UTR 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 62/346 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs768014195; called by muse, mutect2, varscan2
- CIDEA | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs758298543, COSV57597063; called by muse, mutect2, varscan2
- CSRP3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 24/511 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as CD062135; called by muse, mutect2
- EVL | c.28C>T p.R10W (on ENST00000402714 / NM_001330221.2; = p.R12W on NM_016337.3) | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs961379327, COSV101233074, COSV67375764; called by muse, mutect2
- GLI2 | c.2537C>T p.S846L (on ENST00000361492 / NM_001374353.1; = p.S863L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV58038001; called by muse, mutect2, varscan2
- IGFN1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs932786833; called by muse, mutect2
- IL12A | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs371345224; called by muse, mutect2, varscan2
- MAP3K1 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 60/312 reads (19%) | catalogued as COSV68125655; called by muse, mutect2, varscan2
- MCM10 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs753259372, COSV66333608; called by muse, mutect2, varscan2
- METTL24 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs899696732; called by muse, mutect2, varscan2
- MUC5B | c.6647C>T p.S2216L | Missense Mutation (SNP) | VAF 98/965 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs267602740; called by muse, mutect2, varscan2
- ATF7IP2 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJC21 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DTHD1 | c.415T>A p.S139T (on ENST00000456874; = p.S264T on NM_001170700.3) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MAP3K1 | c.1814del p.N605Ifs*51 | Frame Shift Del (DEL) | VAF 52/308 reads (17%) | called by mutect2, pindel, varscan2
- PLCH2 | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- SRD5A3 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST7 | c.1648T>C p.S550P | Missense Mutation (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- STX16 | c.868C>A p.H290N (on ENST00000371141 / NM_001001433.3; = p.H269N on NM_003763.6) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ANKRD11 | c.1596G>A p.Q532= | Silent (SNP) | VAF 104/585 reads (18%) | called by muse, mutect2, varscan2
- CD8A | c.426G>A p.A142= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1339384173, COSV52159495; called by muse, mutect2, varscan2
- MYBPH | c.828G>A p.L276= | Silent (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- PCDHB16 | c.2124C>T p.F708= | Silent (SNP) | VAF 125/999 reads (13%) | catalogued as rs1554282453, COSV53361764; called by muse, mutect2, varscan2
- XKR7 | c.1185C>T p.N395= | Silent (SNP) | VAF 110/536 reads (21%) | catalogued as rs372168274; called by muse, mutect2, varscan2
- CHMP4B | c.-26G>A | 5'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, varscan2
- MLIP | c.613-11844C>T | Intron (SNP) | VAF 17/457 reads (4%) | catalogued as rs1332329803; called by muse, mutect2
- RNY4P30 | chr13:49891000 C>A | 5'Flank (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- SLC26A9 | c.*363G>A | 3'UTR (SNP) | VAF 141/702 reads (20%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.-8C>T | 5'UTR (SNP) | VAF 24/141 reads (17%) | catalogued as rs1231056181, COSV100555014; called by muse, mutect2, varscan2
